Surgical pathology report (de-identified scan), TCGA case TCGA-20-1686, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1686-01A (Primary Tumor).

[page 1 of 5]
TCGA-20-1686

Age:

Sex:

Clinical History/Diagnosis: Pelvic Mass

Source of Specimen(s):

- 1: Cytology -no fee code
- 2: left Ovary and tube
- 3: right Ovary and tube
- 4: Pelvic Peritoneum left
- 5: right Pelvic Peritoneum
- 6: anterior Cul de sac peritoneum
- 7: Omentum
- 8: Omentum nodule
- 9: right Para-colic gutter
- 10: right hemidiaphragm
- 11: left hemidiaphragm
- 12: left paraortic Lymph Node
- 13: left pelvic Lymph Node

Gross Description:

Received in thirteen parts.

Source of Tissue: 1. Cytology.

Source of Tissue: 2. Labeled #2, "left tube and ovary"

Intraoperative Consultation: SEROUS ADENOCARCINOMA.

Gross Description: Received fresh labeled " patient name and medical number, left tube and ovary". It consists of a fallopian tube with attached cystic ovary weighing a total of 345 grams. The cystic ovary measures 11.5 x 10.5 x 7.5 cm. The outer surface is gray-tan, cerebriform with no papillary structures noted. The ovary is sectioned to reveal a multilocular fluid filled cut surface with multiple scattered fleshy areas noted, the largest measuring 7 cm in greatest dimension. The attached fallopian tube measures 4.5 x 0.7 x 0.5 cm. The tube is sectioned to reveal a soft tan-pink cut surface with no obvious masses present. Representative sections submitted in 2A-2I.

Designation of Sections: 2A-2H- random section of ovary, 2I- fallopian tube in relation to ovarian mass

Source of Tissue: 3. Labeled #3, "right tube and ovary":

Gross Description: Received fresh labeled " patient name and medical number,

[page 2 of 5]
right tube and ovary". It consists of a cystic ovary with attached fallopian tube weighing a total of 23 grams. The cystic ovary measures 4 x 3.5 x 2.7 cm. The outer surface is gray-tan and smooth with no papillary structures noted. The ovary is sectioned to reveal a multilocular fluid filled cystic cut surface with one tan-pink fleshy solid area noted measuring 3 cm in greatest dimension. The attached fallopian tube measures 6.5 x 0.5 x 0.5 cm. The outer surface is tan-pink and rough. Multiple small well-circumscribed nodules are identified throughout the serosal surface, the largest measuring 0.3 cm in greatest dimension. Fimbriated ends are identified and are unremarkable. Representative sections submitted in 3A-3C.

Designation of Sections: 3A-3B- ovary, 3C- fallopian tube

Source of Tissue: 4. Labeled #4, "left pelvic peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, left pelvic peritoneum". It consists of four soft red-brown irregular tissue fragments measuring 4.2 x 3 x 1 cm in aggregate. The specimen is serially sectioned and entirely submitted in 4A-4B.

Source of Tissue: 5. Labeled #5, "right pelvic peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, right pelvic peritoneum". It consists of a tan-pink irregular tissue fragment measuring 0.8 x 0.7 x 0.5 cm. The specimen is bisected and entirely submitted in 5A.

Source of Tissue: 6. Labeled #6, "anterior cul de sac peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, anterior cul de sac peritoneum". It consists of a soft tan-pink tissue fragment measuring 0.8 x 0.3 x 0.3 cm. Entirely submitted in 6A.

Source of Tissue: 7. Labeled #7, "omentum"

Gross Description: Received fresh labeled " patient name and medical number, omentum". It consists of a portion of omentum measuring 22 x 12 x 3 cm in greatest dimension. The specimen is sectioned to reveal a soft yellow-tan fibrofatty cut surface with no masses present. Representative sections submitted in 7A-7D.

[page 3 of 5]
Source of Tissue: 8. Labeled #8, "omentum nodule"

Gross Description: Received fresh labeled " patient name and medical number, omentum nodule". It consists of a portion of omentum measuring 8 x 5 x 4 cm. The specimen is sectioned to reveal an ill-defined, firm white nodule measuring 3 x 3 x 2.5 cm. Representative sections submitted in 8A.

Source of Tissue: 9. Labeled #9, "right paracolic gutter peritoneum"

Gross Description: Received fresh labeled " patient name and medical number, right paracolic gutter peritoneum". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 1.8 x 1.7 x 0.5 cm. The specimen is bisected and entirely submitted in 9A.

Source of Tissue: 10. Labeled #10, "right hemidiaphragm"

Gross Description: Received fresh labeled " patient name and medical number, right hemidiaphragm". It consists of a soft tan-pink irregular tissue fragment measuring 0.7 x 0.2 x 0.2 cm. Entirely submitted in 10A.

Source of Tissue: 11. Labeled #11, "left hemidiaphragm"

Gross Description: Received fresh labeled " patient name and medical number, left hemidiaphragm". It consists of a soft tan-pink irregular tissue fragment measuring 1 x 0.3 x 0.3 cm. Entirely submitted in 11A.

Source of Tissue: 12. Labeled #12, "left paraaortic lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, left paraaortic lymph nodes". It consists of a soft yellow-tan irregular fibrofatty tissue fragment measuring 4 x 2 x 2 cm. The specimen is sectioned to reveal two firm tan pink lymph nodes measuring from 2 cm up to 2.5 cm in greatest dimension. The lymph nodes are entirely submitted in 12A-12B.

Source of Tissue: 13. Labeled #13, "left pelvic lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, left pelvic lymph nodes". It consists of four firm yellow-tan lymph nodes measuring from 0.5 up to 3.0 cm in greatest dimension. The lymph nodes are entirely submitted in 13A-13D.

[page 4 of 5]
Designation of Sections: 13A-13B- largest lymph node bisected, 13C- one bisected lymph node, 13D- multiple small lymph nodes

Final Diagnosis:

1. Cytology.

2. Left fallopian tube and ovary; salpingo-oophorectomy:

- High grade papillary serous carcinoma involving ovary and paratubal soft tissue.
- Angiolymphatic invasion is not identified.
- Fallopian tube epithelium is normal.

3. Right fallopian tube and ovary; salpingo-oophorectomy:

- High grade papillary serous carcinoma involving ovary and paratubal soft tissue.
- Angiolymphatic invasion is not identified.
- Fallopian tube with epithelial dysplasia at fimbrial end.

4. Left pelvic peritoneum, excision:

- Metastatic serous carcinoma.

5. Right pelvic peritoneum, excision:

- Metastatic serous carcinoma.

6. Anterior cul de sac peritoneum, excision:

- No tumor seen.

7. Omentum, excision:

- Metastatic serous carcinoma.

8. Omentum nodule, excision:

- Metastatic serous carcinoma (3 cm).

9. Right paracolic gutter peritoneum, excision:

- No tumor seen.

10. Right hemidiaphragm, excision:

- No tumor seen.

11. Left hemidiaphragm, excision:

- No tumor seen.

12. Left para-aortic lymph nodes, excision:

- Two lymph nodes with no tumor seen, (0/2).

[page 5 of 5]
13. Left pelvic lymph nodes, excision:

- Six lymph nodes with no tumor seen, (0/6).
- Metastatic serous carcinoma in perinodal fibrous tissue.

[REDACTED]

Source: NCI Genomic Data Commons file 4102ff39-e45d-42d0-bc48-0896127f5021 (TCGA-20-1686.C87FF195-1793-455A-BB19-E495A915BEFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).